Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A00E, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A00E-01A (Primary Tumor).

100-0-3

Adenocarcinoma, NOS 8140/3

Site: ascending colon C18.2 3/28/11

Sample ID #:

Diagnosis / Diagnoses:

Right hemicolectomy specimen with an ulcerated colon carcinoma conforming to the histological type of a poorly differentiated colorectal adenocarcinoma, located 1.5 cm aborally from Bauhin's valve and circularly occupying the intestinal wall over a length of 8 cm. Invasive spread of tumor within all layers of the intestinal wall, extending into the mesocolic fatty tissue and as far as directly below the serosa.

Appendix tumor-free and with post-inflammatory fibrosis of the wall.

Oral and aboral resection margins and large omentum tumor-free.

41 regional lymph nodes tumor-free and with uncharacteristic reactive changes.

Tumor stage thus pT3 pN0 (0/41) L0 V0 R0; G3

Case ID (circle):		
State Reviewed: 5/16/11		

Source: NCI Genomic Data Commons file 3200d192-323f-4c36-84a3-22ac77d99514 (TCGA-AA-A00E.B999FAB8-FBF9-405F-9E6F-81A6E2204363.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).